Somatic mutation profile of tumor specimen 0DIAC2 from CCDI case PBBVLR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Germinoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.2 years (5,916 days).
Specimen 0DIAC2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 340fc15d-5f14-4f47-ad9d-f1c00700348d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIACD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9f22de3-0b1d-40e1-b8ae-2f556382fa51

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CBL | c.1258C>G p.R420G | Missense Mutation (SNP) | VAF 50/866 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1314298, COSV50630874, COSV50653789; called by muse, mutect2
